Somatic mutation profile of tumor specimen TCGA-QK-A8ZA-01A (aliquot TCGA-QK-A8ZA-01A-11D-A391-08) from TCGA case TCGA-QK-A8ZA, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; Tumor grade: G2; Age at diagnosis: 60.2 years (21,979 days).
Specimen TCGA-QK-A8ZA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1331d08e-6662-481c-ae53-50e6e7696413.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-A8ZA-10A (Blood Derived Normal), aliquot TCGA-QK-A8ZA-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96f6f9b7-b342-4cae-9844-1af8cc49e53b

The open-access MAF lists 130 somatic variants for this specimen: 96 protein-altering or splice-affecting, 32 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 32, Nonsense Mutation 6, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 35/50 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.13604A>T p.N4535I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320822857, COSV101291391; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4087G>A p.G1363R | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99720224; called by mutect2, varscan2
- AKAP12 | c.4645C>A p.L1549I | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV99483973; called by muse, mutect2, varscan2
- ASPSCR1 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60727916; called by muse, mutect2, varscan2
- ATP13A4 | c.3259C>G p.L1087V | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as COSV100710553; called by muse, mutect2, varscan2
- BAG3 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs199991063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BEX5 | c.283A>T p.I95L | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.567); catalogued as COSV100375075; called by muse, mutect2, varscan2
- BPIFB4 | c.927G>T p.G309= | Splice Region (SNP) | VAF 54/159 reads (34%) | catalogued as COSV100971600; called by muse, mutect2, varscan2
- C8orf34 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV100298832; called by muse, mutect2, varscan2
- CAMK1D | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.353); catalogued as rs765682396, COSV66606122; called by muse, mutect2, varscan2
- CDKL4 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs370476409, COSV101115440; called by muse, mutect2, varscan2
- CGN | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99642609; called by muse, mutect2
- CHMP2A | c.522C>A p.S174R | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV99448273; called by muse, mutect2, varscan2
- CLNS1A | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.87); catalogued as COSV99628102; called by muse, mutect2
- COL28A1 | c.2458T>C p.F820L | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs375679131, COSV68080574; called by muse, mutect2, varscan2
- CPSF6 | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as COSV99879541; called by muse, mutect2, varscan2
- CUL9 | c.4795C>T p.H1599Y | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV99335761; called by muse, mutect2, varscan2
- CYSLTR2 | c.812T>C p.L271S | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99935316; called by muse, mutect2, varscan2
- DCP1B | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99767747; called by muse, mutect2, varscan2
- DENND2A | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.133); catalogued as rs1356614461, COSV99326610; called by muse, mutect2, varscan2
- DNAH5 | c.4504C>T p.L1502F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99452196; called by muse, mutect2, varscan2
- EBF3 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as COSV100799495, COSV62481841; called by muse, mutect2, varscan2
- EPHA8 | c.2744C>T p.A915V | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as COSV99385362; called by muse, mutect2, varscan2
- ERBB4 | c.3409C>G p.P1137A | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100726637; called by muse, mutect2, varscan2
- EYA1 | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as COSV58163595; called by muse, mutect2, varscan2
- FRMPD1 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV100899600; called by muse, mutect2, varscan2
- GALNT18 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs769082072, COSV99925338; called by muse, mutect2, varscan2
- GBP4 | c.242C>G p.P81R | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs567028572, COSV100864435; called by muse, mutect2, varscan2
- GP2 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.577); catalogued as COSV100221580; called by muse, mutect2, varscan2
- GTF2A1 | c.890A>T p.E297V | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV53337576, COSV99993492; called by muse, mutect2, varscan2
- GTSE1 | c.1541C>G p.S514C | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV101483235; called by muse, mutect2, varscan2
- HECW2 | c.2626G>A p.E876K | Missense Mutation (SNP) | VAF 63/82 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99648150; called by muse, mutect2, varscan2
- HFM1 | c.92C>A p.S31* | Nonsense Mutation (SNP) | VAF 29/87 reads (33%) | catalogued as COSV99646455; called by muse, mutect2, varscan2
- HIP1 | c.2623G>A p.A875T | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417920; called by muse, mutect2, varscan2
- HLA-DPB1 | c.417C>A p.H139Q | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs751346150, COSV101331033; called by muse, mutect2, varscan2
- HNRNPUL2 | c.929A>G p.E310G | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV100079747; called by muse, mutect2, varscan2
- HTR2C | c.1199G>C p.R400T | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.995); catalogued as COSV99350283; called by muse, mutect2, varscan2
- IL1F10 | c.144A>T p.R48S | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100520215; called by muse, mutect2, varscan2
- ITGA4 | c.1404T>G p.I468M | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV99276640; called by muse, mutect2, varscan2
- KALRN | c.1804G>C p.E602Q | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV99566177; called by muse, mutect2, varscan2
- KCNA2 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.528); catalogued as rs770338663, COSV60371672; called by muse, mutect2, varscan2
- KRT34 | c.840T>G p.I280M | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV101222696; called by muse, mutect2, varscan2
- LGSN | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101040612; called by muse, mutect2, varscan2
- LMOD3 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as rs1052567698, COSV101342016; called by muse, mutect2, varscan2
- MED25 | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV100457757; called by muse, mutect2, varscan2
- MEP1A | c.69G>T p.P23= | Splice Region (SNP) | VAF 22/252 reads (9%) | catalogued as COSV100042945; called by muse, mutect2
- NAE1 | c.1457G>C p.G486A | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99323228; called by muse, mutect2, varscan2
- NLGN4X | c.1111G>T p.V371F | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99321969, COSV99323099; called by muse, mutect2, varscan2
- NLRC5 | c.4993G>A p.E1665K | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV99347848; called by muse, mutect2, varscan2
- NOTCH1 | c.1264C>A p.P422T | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV53052320, COSV99490172; called by muse, mutect2, varscan2
- OR2D3 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs771298623, COSV58574309; called by muse, mutect2, varscan2
- PCDHB16 | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99502513; called by muse, mutect2, varscan2
- PEAR1 | c.2923G>A p.D975N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.749); catalogued as rs1299315192, COSV99442018; called by muse, mutect2, varscan2
- PHC2 | c.361A>G p.S121G | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99931255; called by muse, mutect2, varscan2
- PHF3 | c.1436C>G p.S479C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV100013705; called by muse, mutect2, varscan2
- PKD1 | c.12268C>T p.L4090F (on ENST00000262304 / NM_001009944.3; = p.L4089F on NM_000296.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.627); catalogued as rs1484777711, COSV99238660; called by muse, mutect2, varscan2
- PKD2L1 | c.2300C>A p.P767Q | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV100559414; called by muse, mutect2, varscan2
- PLOD1 | c.750G>C p.L250F | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.448); catalogued as COSV99538717; called by muse, mutect2, varscan2
- PLOD2 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV99283067; called by muse, mutect2, varscan2
- PM20D1 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs199717760, COSV65648532; called by muse, mutect2, varscan2
- POT1 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); catalogued as COSV100714108; called by muse, mutect2, varscan2
- PPARD | c.390C>G p.F130L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV100283244; called by muse, mutect2, varscan2
- PPME1 | c.810G>C p.K270N | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV100076584; called by muse, mutect2
- PTGIR | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as COSV99355028; called by muse, mutect2, varscan2
- RALGAPB | c.3674A>G p.D1225G | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99485538; called by muse, mutect2, varscan2
- RANBP17 | c.2131G>C p.E711Q | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.086); catalogued as COSV101206348; called by muse, mutect2, varscan2
- RASGRP2 | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100818304, COSV62450841; called by muse, mutect2, varscan2
- RAVER1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.861); catalogued as rs767186725, COSV53345953; called by muse, mutect2, varscan2
- RFX3 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1294373274, COSV100175541; called by muse, mutect2, varscan2
- SCNN1D | c.1403G>A p.R468K (on ENST00000338555; = p.R632K on NM_001130413.4) | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.124); catalogued as COSV100330206; called by muse, mutect2, varscan2
- SEMA3F | c.1606T>G p.S536A | Missense Mutation (SNP) | VAF 64/86 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99137713; called by muse, mutect2, varscan2
- SLC43A3 | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as COSV100725239; called by muse, mutect2, varscan2
- SLC4A8 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs374704511; called by muse, mutect2, varscan2
- SPAG17 | c.1945C>G p.Q649E | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.083); catalogued as COSV100309903; called by muse, mutect2, varscan2
- STOML2 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV100521400; called by muse, mutect2, varscan2
- TBC1D9 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.912); catalogued as rs758658105, COSV71306753; called by muse, mutect2, varscan2
- TECPR2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as rs1193211122, COSV100850138; called by muse, mutect2, varscan2
- TFE3 | c.1501C>G p.L501V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.503); catalogued as COSV100252722; called by muse, mutect2, varscan2
- TMEM132D | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs749108405, COSV70597865; called by muse, mutect2, varscan2
- TMX3 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 31/49 reads (63%) | catalogued as rs376484673; called by muse, mutect2, varscan2
- TNFAIP6 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99694009; called by muse, mutect2
- TP53BP2 | c.44A>G p.Y15C | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100636737; called by muse, mutect2, varscan2
- TTLL1 | c.820G>T p.G274C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56739552, COSV99840481; called by muse, mutect2, varscan2
- TTN | c.23873C>A p.A7958E (on ENST00000591111; = p.A7031E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/63 reads (51%) | PolyPhen possibly damaging (0.748); catalogued as COSV100622698; called by muse, mutect2, varscan2
- VWA8 | c.1720C>T p.P574S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV99864684; called by muse, mutect2, varscan2
- WASF3 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs1227239955, COSV58970574; called by muse, mutect2, varscan2
- WDR72 | c.2315T>G p.M772R | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV100854898; called by muse, mutect2, varscan2
- ZBTB6 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.031); catalogued as COSV101022043; called by muse, mutect2, varscan2
- ZFP2 | c.998A>C p.K333T | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100797097; called by muse, mutect2, varscan2
- ZNF175 | c.1641C>A p.S547R | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as COSV99219653; called by muse, mutect2, varscan2
- ZNF333 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV99469419; called by muse, mutect2, varscan2
- ZNF790 | c.1868A>T p.E623V | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100764862; called by muse, mutect2, varscan2
- CUL3 | c.1307dup p.L436Ffs*9 | Frame Shift Ins (INS) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- N4BP3 | c.460del p.C154Afs*5 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, pindel, varscan2
- PYGB | c.2345dup p.M782Ifs*34 | Frame Shift Ins (INS) | VAF 31/80 reads (39%) | called by mutect2, pindel, varscan2
- ACTN3 | c.621C>T p.Y207= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs557104178, COSV72207614; called by muse, mutect2, varscan2
- AGL | c.603G>A p.V201= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV99649744; called by muse, mutect2, varscan2
- ARFGEF3 | c.2589T>C p.Y863= | Silent (SNP) | VAF 64/93 reads (69%) | catalogued as COSV99294244; called by muse, mutect2, varscan2
- ASH1L | c.4929G>T p.R1643= | Silent (SNP) | VAF 84/159 reads (53%) | catalogued as rs771860164, COSV100853538; called by muse, mutect2, varscan2
- CLEC4F | c.1368A>G p.E456= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as COSV99713901; called by muse, mutect2, varscan2
- CSMD1 | c.6669C>T p.L2223= (on ENST00000520002; = p.L2222= on NM_033225.6) | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs755072803, COSV100151559; called by muse, mutect2, varscan2
- CYBB | c.861G>C p.R287= | Silent (SNP) | VAF 9/123 reads (7%) | catalogued as COSV101059797, COSV101059834; called by muse, mutect2
- DCTN1 | c.1764G>A p.L588= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV100721011; called by muse, mutect2, varscan2
- DIPK2A | c.1203G>A p.E401= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs755349514, COSV100237375; called by muse, mutect2, varscan2
- H1-3 | c.135C>T p.I45= | Silent (SNP) | VAF 80/245 reads (33%) | catalogued as rs200463287, COSV55097131, COSV99768859; called by muse, mutect2, varscan2
- KMT2A | c.9855C>T p.I3285= | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as COSV63293119; called by muse, mutect2, varscan2
- MFSD1 | c.993C>T p.I331= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV99963980; called by muse, mutect2, varscan2
- MPDZ | c.63G>C p.L21= | Silent (SNP) | VAF 83/123 reads (67%) | catalogued as COSV100063811; called by muse, mutect2, varscan2
- NR2F1 | c.1209C>A p.I403= | Silent (SNP) | VAF 58/101 reads (57%) | catalogued as COSV100504740; called by muse, mutect2, varscan2
- OMA1 | c.723T>C p.Y241= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV100678308; called by muse, mutect2, varscan2
- OR10J5 | c.276C>A p.I92= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as COSV100604760; called by muse, mutect2, varscan2
- OR5F1 | c.390G>T p.L130= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV99558819; called by muse, mutect2, varscan2
- OSBP2 | c.1959C>T p.F653= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs747594477, COSV100213491; called by muse, mutect2, varscan2
- PAQR7 | c.819G>A p.Q273= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV100961706; called by muse, mutect2, varscan2
- PCDHB2 | c.144C>A p.A48= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV99523414; called by muse, mutect2, varscan2
- PPP1R17 | c.402C>G p.L134= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100566435; called by muse, mutect2, varscan2
- PRKDC | c.10068T>A p.A3356= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV100041871; called by muse, mutect2, varscan2
- PTPN4 | c.1449G>A p.S483= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs374203083; called by muse, mutect2, varscan2
- RB1 | c.1980C>T p.L660= | Silent (SNP) | VAF 47/104 reads (45%) | called by muse, mutect2, varscan2
- RELN | c.6924C>T p.I2308= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as rs1186168682, COSV58996842, COSV59031603; called by muse, mutect2
- RIMS2 | c.3825C>G p.V1275= | Silent (SNP) | VAF 25/27 reads (93%) | catalogued as COSV99179485; called by muse, varscan2
- RXRB | c.717C>T p.Y239= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs1222276421, COSV100807807; called by muse, mutect2, varscan2
- RYR2 | c.5811A>G p.Q1937= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100772045; called by muse, mutect2, varscan2
- SPAG17 | c.5694T>C p.N1898= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs761401705, COSV100309902; called by muse, mutect2, varscan2
- SREBF1 | c.1038C>T p.L346= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99889241; called by muse, mutect2, varscan2
- TNFRSF1A | c.114G>A p.E38= | Silent (SNP) | VAF 53/114 reads (46%) | catalogued as COSV99369811; called by muse, mutect2, varscan2
- UGT1A5 | c.537T>C p.D179= | Silent (SNP) | VAF 115/201 reads (57%) | catalogued as rs1471082533, COSV100530632; called by muse, mutect2, varscan2
- AC074085.2 | n.189dup | RNA (INS) | VAF 14/83 reads (17%) | called by mutect2, pindel, varscan2
- RTEL1 | c.3652+147G>T | Intron (SNP) | VAF 45/67 reads (67%) | catalogued as COSV99423198; called by muse, mutect2, varscan2
